Surgical pathology report (de-identified scan), TCGA case TCGA-E1-A7YM, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Duke, specimen TCGA-E1-A7YM-01A (Primary Tumor).

[page 1 of 4]
Patient: [REDACTED]

Surgical Pathology: Corrected [REDACTED] Acc: [REDACTED]

Surg Path

CLINICAL HISTORY:

Brain neoplasm not otherwise specified. Left medial temporal lesion.

GROSS EXAMINATION:

A. "Brain tissue (AF1)", received fresh for frozen section and placed in formalin at [REDACTED] on [REDACTED] is a 1.3 x 0.2 x 0.1 cm aggregate of soft tan-white tissue. The specimen is frozen entirely as representative AF1 and the frozen section remnant is submitted in A1.

B. "Brain tissue", received unfixed and placed in formalin at [REDACTED] on [REDACTED] is a 4.6 x 3.5 x 1.1 cm aggregate of brain tissue of which some fragments have a well defined gyri and foci. Sectioning demonstrates a well demarcated gray white matter. Representative sections in B1-4 (approximately 50% of specimen submitted).

INTRA OPERATIVE CONSULTATION:

A. "Brain tissue": AF1 (in toto)-glioma, low grade (

MICROSCOPIC EXAMINATION:

Microscopic examination shows brain infiltrated by a glial neoplasm characterized by cellular pleomorphism, and microvascular changes. A ki-67 immunostain yields a proliferation rate of 10%. No necrosis is seen.

Tumor is noted to be growing in Virchow-Robin spaces along blood vessels, as well as in the subarachnoid region. Occasional satellitosis is noted, suggestive of an oligodendrocytic component, however the majority of the histology is more compatible with a diagnosis of astrocytoma. Additionally, a GFAP immunostain decorates large reactive astrocytes.

IMMUNOHISTOCHEMICAL FINDINGS:

Ki-67 immunostaining reveals a proliferation rate of 10%. GFAP highlights large reactive astrocytes. HAM-56 fails to detect significant macrophages.

The immunoperoxidase tests reported herein were developed and their performance characteristics were determined by the

. Some of them may not be cleared or approved by the U.S. Food and Drug Administration. The FDA has determined that such clearance or approval is not necessary. These tests are used for clinical purposes. They should not be regarded as investigational or for research. This laboratory is certified under the Clinical Laboratory Improvement Amendments of 1988 (CLIA) as qualified to perform high complexity clinical testing.

DIAGNOSIS:

A. BRAIN TISSUE; NEEDLE BIOPSY:

ANAPLASTIC ASTROCYTOMA (WHO GRADE III)

B. BRAIN TISSUE; RESECTION:

ANAPLASTIC ASTROCYTOMA (WHO GRADE III)
SEE COMMENT.

ICD-O-3
Astrocytoma, grade III 9401/3
Site Brain, supratentorial NOS
path C71.0
Brain NOS C71.9
9/5/14

[page 2 of 4]
~~COMMENT: 1p19q mutation analysis has been ordered and will be issued in a separate report.~~

~~I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).~~

M.D.

Electronically signed: [REDACTED]

ADDENDUM 1:

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

FISH INTERPRETATION SUMMARY:

FISH MARKER	INTERPRETATION	% OF TUMOR CELLS EXHIBITING ABNORMALITY	FINDINGS/STATUS
EGFR (7p12)	ABNORMAL	30%	GAIN
MET (7q31)	ABNORMAL	28%	GAIN
7 CEP	ABNORMAL	25%	GAIN
KIT (4q12)			NOT ORDERED
4 CEP			NOT ORDERED
PTEN (10q23)	NORMAL		INTACT
10 CEP	NORMAL		INTACT
CDKN2A (9p21)	NORMAL		INTACT
9 CEP	NORMAL		INTACT
1p36	ABNORMAL	56%	LOSS
1q25	CONTROL INTACT		
1p32	NORMAL		INTACT
1qtel	CONTROL INTACT		
19q13	NORMAL		INTACT
19p13	CONTROL INTACT		

EGFR, 7 CEP, PTEN, AND 10 CEP: 2 OF 4 ABNORMAL MARKERS.
MET EXHIBITS POLYSOMY, 9p21 IS INTACT, 1p36 EXHIBITS LOSS, AND 1p32 AND 19q ARE INTACT.

COMMENT: THIS TUMOR EXHIBITS PARTIAL LOSS OF 1p19q WHICH CORRELATES WITH A PHENOTYPIC APPEARANCE OF OLIGOASTROCYTOMA.

COMMENT: A MULTIVARIATE SURVIVAL ANALYSIS OF PATIENTS WITH ANAPLASTIC ASTROCYTOMAS REVEALS THAT THE HAZARD OF SHORT SURVIVAL AMONG PATIENTS WITH 0-2 ABNORMAL MARKERS (OUT OF 4) WAS SIGNIFICANTLY LOWER THAN THAT FOUND WITH PATIENTS WITH >2 MARKERS (P=0.037) EVEN AFTER ADJUSTMENT FOR AGE EFFECT.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 2:

BRAIN TISSUE CONTAINING ANAPLASTIC ASTROCYTOMA (WHO GRADE III; [REDACTED] BLOCK B3).

IHC Antibody:	Interpretation IHC	Score (0-3+)	% of Tumor Cells of Exhibiting Staining	ACIS III SCORE
---------------	-----------------------	-----------------	--	-------------------

[page 3 of 4]
CD/45-LCA

10%

Ki-67

NOT ORDERED

MGMT	POSITIVE		40%	39%
EGFR WT	POSITIVE	2+	80%	
EGFR VIII	NEGATIVE		0%	0%
PTEN	NOT ORDERED			
pS6	NEGATIVE	2+	10%	
pAKT	NEGATIVE	2+	5%	
pMAPK	NEGATIVE	2+	5%	
CA-IX	NEGATIVE		0%	
VEGF	POSITIVE	2+	20%	= 40
PDGFr Alpha	WIDESPREAD		60%	
PDGFr Beta	WIDESPREAD		80%	
VEGFr-KDR	NEGATIVE	2+	5%	= 10
HIF2 Alpha:	NOT ORDERED			

Please see Image Cytometry Report [REDACTED] for results of supplementary tests.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 3:

MGMT PROMOTER METHYLATION REAL TIME PCR ANALYSIS

Received [REDACTED] from [REDACTED]
is a copy of an MGMT Promoter Methylation Assay, obtained at the request
of Dr. [REDACTED] on paraffin block [REDACTED]
) . The complete report from [REDACTED] is on file in the [REDACTED]

Result:

MGMT PROMOTER METHYLATION NOT IDENTIFIED.

Methodology:

DNA is isolated from formalin-fixed, paraffin-embedded (FFPE) specimen.
Molecular analysis of the MGMT gene is performed by methylation-specific PCR.
Molecular-based testing is highly accurate but as in any laboratory test, rare diagnostic errors may occur.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

Printed by: [REDACTED]

3 of 4

[page 4 of 4]
ADDENDUM 4:

Please see MOLECULAR DIAGNOSTICS Report [REDACTED] for complete report.

Testing was performed on sample [REDACTED] BLOCK B3.

IDH1 MUTATION TESTING WITH REFLEX TO IDH2

INTERPRETATION:

IDH1 GENE NUCLEOTIDE VARIANT DETECTED. p.Arg49His (c.146G>A).

IDH2 GENE MUTATIONS NOT DETECTED. SEE OBJECTIVE FINDINGS AND COMMENT.

COMMENT: A single missense nucleotide change leading to amino acid change p.Arg49His is detected in the IDH1 gene. This nucleotide alteration is not a previously cited polymorphism, nucleotide change or mutation. Thus, the significance of this sequence change is unclear.

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

ADDENDUM 5:

EGFR VIII IMMUNOHISTOCHEMISTRY: NEGATIVE

None of the tumor cells exhibit staining for EGFR VIII (Score = 0).

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

M.D.

Electronically signed: [REDACTED]

Performed by: SURGICAL PATHOLOGY

Ordering MD:

Printed by: [REDACTED]

4 of 4

Source: NCI Genomic Data Commons file 891a4c3a-d871-4812-9b9e-9b66d796c043 (TCGA-E1-A7YM.FC2E7F8E-0C21-457D-92A1-0052057DF808.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).